CCDI case PBCGUR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/b432d245-4b6c-46d3-9706-1c0c363ae1fb

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 1.2 years (440 days).

Biospecimens (2 samples)
- Sample 0DSHT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSHTB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
